CGCI case HTMCP-01-20-00802 — HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma (CGCI-HTMCP-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/571e6075-f306-4775-8025-d43197c114a5

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: primary; Age at diagnosis: 54.3 years (19,827 days); Year of diagnosis: 2017; Method of diagnosis: Biopsy; Ann Arbor clinical stage: Stage III; Ann Arbor pathologic stage: Stage III; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,359 days (3.7 years); Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Iliac-external.
   Pathology details: Lymph node involved site: Paraaortic.
   Pathology details: Additional pathology findings: Percent follicular component > 10%; Lymph node involved site: Axillary; Tumor largest dimension diameter: 6.1 cm.
   Pathology details: Lymph node involved site: Inguinal.
   Pathology details: Lymph node involved site: Supraclavicular.
   Pathology details: Lymph node involved site: Iliac-external.
   Pathology details: Lymph node involved site: Splenic.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (5 entries)
- Days to follow up: 0 days; Imaging type: PET; Imaging result: Negative.
- Days to follow up: 535 days (1.5 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 535 days (1.5 years).
- Days to follow up: 981 days (2.7 years); Disease response: With Tumor.
- Days to follow up: 1,074 days (2.9 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 1,074 days (2.9 years).
- Days to follow up: 1,359 days (3.7 years); Disease response: Tumor Free; Imaging type: PET; Imaging result: Indeterminate.

Molecular and laboratory tests
- BCL2 (IHC): Positive.
- BCL6 (IHC): Negative; Specialized molecular test: BCL6 > 30%.
- BCL6: Positive; Specialized molecular test: BCL6 > 30%.
- CCND1: Negative.
- CD10 (IHC): Negative; Specialized molecular test: CD10 > 30%.
- CD10: Positive; Specialized molecular test: CD10 > 30%.
- CD19: Positive.
- CD20 (IHC): Positive.
- CD20: Positive.
- CD23: Positive.
- CD3 (IHC): Negative.
- CD30: Negative.
- CD79A (IHC): Equivocal.
- IGK: Abnormal, NOS; Clonality: Clonal.
- IRF4 (IHC): Equivocal; Specialized molecular test: MUM1 > 30%.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- TP53 (IHC): Negative; Specialized molecular test: P53 > 20%.
- Lactate Dehydrogenase 560 [Blood test normal range upper: 227].
- Epstein-Barr Virus (ISH): Negative.

Other clinical attributes
- Day 0: Cdc hiv risk factors: Heterosexual Contact.
- Day 0: Comorbidities: Hepatitis C Infection.
- Day 0: Risk factors: Hepatitis C Infection.
- Day 0: Weight: 88 kg; Height: 182.9 cm; BMI: 26.3; CD4 count: 476; Haart treatment indicator: Yes; HIV viral load: 298.
- Day 0: AIDS risk factors: Herpes Simplex Virus.
- Comorbidities: HIV/AIDS.
- Risk factors: HIV/AIDS.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (2 samples)
- Sample HTMCP-01-20-00802-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-01-20-00802-02A: Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response; Tobacco smoking history indicator: 1; Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- History of disease: Year of HIV diagnosis: 1990; Prior aids conditions: Herpes simplex: chronic ulcers (> 1 month's duration) or bronchitis, pneumonitis or esophagitis (onset at age > 1 month); Haart therapy prior to diagnosis: Yes; Haart therapy at diagnosis: Yes; History relevant infectious diagnosis: Hepatitis C.
- Primary pathology: Follicular component percent: > 10%; Extranodal site involvement: 0; Method initial path diagnosis: Biopsy (all types); Days from index date to tumor sample procurement: 708; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: para-aortic.
- Primary pathology, Tumor tissue sites: Submitted tumor site: No Known Extranodal Involvement.
- Tests performed: LDH level: 560.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunophenotypic analysis tested: CD19.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: CD23.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD30.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunophenotypic analysis tested: Cyclin D1.
- New tumor event: New tumor event type: Distant Metastasis; New tumor event site: Lymph Node(s); New tumor event surgery: Yes; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Follow-up form: Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event type: Distant Metastasis; New tumor event site: Lymph Node(s); New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-20-00802-02A-01E-18945:
- % tumour top: 95
- % tumour bottom: 95

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-20-00802-02A-01S-18945:
- % tumour top: 95
- % tumour bottom: 95
